Somatic mutation profile of tumor specimen TCGA-AJ-A3OK-01A (aliquot TCGA-AJ-A3OK-01A-12D-A228-09) from TCGA case TCGA-AJ-A3OK, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 73.5 years (26,851 days).
Specimen TCGA-AJ-A3OK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fc31015-e19c-4589-8fe9-0f2254c6df6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A3OK-10A (Blood Derived Normal), aliquot TCGA-AJ-A3OK-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c735ffa-b4cf-4e2e-a30e-473c473df0f7

The open-access MAF lists 797 somatic variants for this specimen: 567 protein-altering or splice-affecting, 216 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 504, Silent 216, Nonsense Mutation 41, Frame Shift Del 11, Intron 5, Splice Region 5, Frame Shift Ins 3, 3'Flank 3, RNA 3, 5'Flank 3, Splice Site 3.

Variants (750 of 797; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.1363C>T p.R455* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as rs886039668, COSV100800475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL11A2 | c.3100C>T p.R1034C (on ENST00000341947 / NM_080680.3; = p.R927C on NM_080679.2) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs121912947, CM993117, COSV59497876; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ETFDH | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780768015, CM083497, COSV100306677; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MAST1 | c.1549G>A p.G517S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1568413207, COSV99262152; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MED12 | c.6476A>C p.Q2159P | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.84); catalogued as rs1085307941, COSV100375591, COSV61336267; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MMAB | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs771053425, COSV99904456; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- NEK9 | c.1489C>T p.R497* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as rs757011098, COSV53131823; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF2 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as rs74315496, CD931032, CM930515, COSV58519772; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 37/92 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs121913294, CM074465, CM102472, COSV100911374, COSV64288961, COSV64302184; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.1026+1G>A p.X342_splice | Splice Site (SNP) | VAF 10/32 reads (31%) | hotspot (GDC flag); catalogued as rs786201041, CS043794, CS110216, COSV64288702, COSV64289135, COSV64293873; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ROBO4 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs201393279; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AADACL4 | c.1132G>A p.G378R | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771450117, COSV100879338; called by muse, mutect2, varscan2
- ABCA4 | c.6223A>G p.N2075D | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100933004; called by muse, mutect2, varscan2
- ABCA6 | c.510C>A p.Y170* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV99445606; called by muse, mutect2, varscan2
- ABCB4 | c.3472G>A p.A1158T (on ENST00000265723 / NM_018849.3; = p.A1151T on NM_000443.4) | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs138850786; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC2 | c.1882C>T p.R628* | Nonsense Mutation (SNP) | VAF 22/69 reads (32%) | catalogued as rs775410341, COSV64984500; called by muse, mutect2, varscan2
- ABCF2 | c.947C>T p.T316M | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV99733941; called by muse, mutect2
- ABHD12B | c.808C>T p.R270C (on ENST00000337334 / NM_001206673.2; = p.R193C on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.849); catalogued as rs200066805, COSV99368165; called by muse, mutect2, varscan2
- ABHD16B | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs908615249, COSV53861456; called by muse, mutect2, varscan2
- AC011462.1 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1200370519, COSV99524379; called by muse, mutect2, varscan2
- ACTN3 | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as rs369005221; called by muse, mutect2, varscan2
- ACTR10 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs760553331, COSV99580845; called by muse, mutect2, varscan2
- ACTR1A | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs778045034, COSV64023355; called by muse, mutect2, varscan2
- ACTR1A | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.159); catalogued as rs1313811564, COSV64023833; called by muse, mutect2, varscan2
- ADAMTS14 | c.2738C>T p.T913M | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as rs570765817, COSV100941287; called by muse, mutect2, varscan2
- ADAMTS5 | c.2098C>T p.R700W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs775648082, COSV53175705; called by mutect2, varscan2
- ADAMTS7 | c.2311G>A p.A771T | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs533435962, COSV101182998; called by muse, mutect2, varscan2
- ADARB2 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV67224652; called by muse, mutect2
- ADGRA1 | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.59); catalogued as rs1183617089, COSV66926027; called by muse, mutect2
- ADGRG7 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.816); catalogued as rs140959989; called by muse, mutect2, varscan2
- AIFM1 | c.73G>A p.V25I | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.055); catalogued as COSV99780691; called by muse, mutect2, varscan2
- AKT1 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as rs1219649544, COSV100837901; called by muse, mutect2, varscan2
- ALLC | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as rs201366958; called by muse, mutect2, varscan2
- ALOX15B | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as rs763925528, COSV101205555; called by muse, mutect2, varscan2
- ALS2 | c.1501C>T p.R501W | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as rs766279865, COSV99968599; called by muse, mutect2, varscan2
- ANAPC2 | c.1289C>T p.T430M | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1441997576, COSV100118843, COSV60572913; called by muse, mutect2, varscan2
- ANKEF1 | c.883G>A p.G295S | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs369257705, COSV65693824; called by muse, mutect2, varscan2
- ANKK1 | c.1891C>T p.H631Y | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100392646; called by muse, mutect2, varscan2
- ANKRD13B | c.601C>A p.R201S | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.374); catalogued as rs937104091, COSV101198844; called by mutect2, varscan2
- AP1B1 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs760201939, COSV100434303; called by muse, mutect2, varscan2
- AP2A2 | c.2687C>T p.T896M | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.766); catalogued as rs748220772, COSV59965070; called by muse, mutect2, varscan2
- ARFGEF2 | c.3383G>A p.R1128Q | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100903939; called by muse, mutect2, varscan2
- ARHGAP21 | c.2968A>G p.S990G | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs528737389, COSV100255650; called by muse, mutect2, varscan2
- ARHGAP36 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as rs1256533982, COSV52267805, COSV99357197; called by muse, mutect2, varscan2
- ARHGAP36 | c.1550C>T p.A517V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs371444281, COSV99357132; called by muse, mutect2, varscan2
- ARHGAP4 | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs781952339, COSV100603738; called by muse, mutect2, varscan2
- ARHGEF18 | c.1246G>A p.A416T (on ENST00000359920 / NM_001130955.2; = p.A312T on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as rs573670041, COSV60469448; called by muse, mutect2, varscan2
- ARHGEF2 | c.350G>A p.R117Q (on ENST00000361247 / NM_001162383.2; = p.R90Q on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as rs753323497, COSV58112072; called by muse, mutect2, varscan2
- ARNT2 | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs370180129, COSV57586033; called by muse, mutect2, varscan2
- ASTN2 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs758127962, COSV100523981, COSV100528998; called by muse, mutect2, varscan2
- ASXL1 | c.3212C>T p.A1071V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); catalogued as rs531415735, COSV100037397; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATG13 | c.1475T>C p.L492S (on ENST00000359513 / NM_001346321.1; = p.L455S on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100365451; called by muse, mutect2, varscan2
- ATP12A | c.2705G>A p.R902Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs367898749; called by muse, mutect2, varscan2
- ATP2A1 | c.1823C>T p.T608M | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs764667200, COSV100706776; called by muse, mutect2, varscan2
- ATP6V0A1 | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as COSV99230318; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1957T>C p.W653R | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as rs1266093701, COSV100022512; called by muse, mutect2, varscan2
- ATRIP | c.2192C>T p.S731L (on ENST00000320211 / NM_130384.3; = p.S704L on NM_032166.4) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200785749, COSV99603821; called by muse, mutect2
- ATXN7L2 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs766137202, COSV100881296; called by muse, mutect2, varscan2
- AUTS2 | c.2497C>T p.R833* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as rs1554487952, COSV100714748; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAG6 | c.1624C>T p.R542W (on ENST00000676571; = p.R495W on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1484713331, COSV99276290; called by muse, mutect2, varscan2
- BAMBI | c.598G>A p.G200R | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1280562244, COSV100977474; called by muse, varscan2
- BANP | c.542C>T p.S181L (on ENST00000286122; = p.S150L on NM_017869.4) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.963); catalogued as rs143791417; called by muse, mutect2, varscan2
- BAZ1A | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.328); catalogued as rs774051075, COSV100701080; called by muse, mutect2, varscan2
- BBX | c.1456G>A p.V486I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs368835354, COSV99065622; called by muse, varscan2
- BCL6 | c.1273C>A p.L425I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99215292; called by muse, mutect2, varscan2
- BCL9 | c.3743C>T p.T1248M | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs138508726; called by muse, mutect2, varscan2
- BEND2 | c.2011C>T p.R671W | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.895); catalogued as rs747951664, COSV101191720; called by muse, mutect2, varscan2
- BICRA | c.3416C>T p.T1139M | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.271); catalogued as rs552885093, COSV101194215; called by muse, mutect2, varscan2
- BOC | c.1021A>G p.K341E | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as COSV99847896; called by muse, mutect2
- BRCC3 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as rs1395711009, COSV57462607; called by muse, mutect2, varscan2
- BRD1 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs779060123, COSV53462247; called by muse, mutect2, varscan2
- BRDT | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs140481537; called by muse, mutect2, varscan2
- BRF1 | c.1724C>T p.T575M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs989494665, COSV59266003; called by muse, mutect2, varscan2
- BRPF1 | c.1651C>T p.R551W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100121071; called by muse, mutect2, varscan2
- BSN | c.8824C>T p.R2942W | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs757590434, COSV56527777; called by mutect2, varscan2
- BTNL8 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as rs748602705, COSV51460359; called by muse, mutect2, varscan2
- C1QTNF9 | c.626C>T p.T209M | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs557592254, COSV59658470; called by muse, mutect2
- C1orf159 | c.1012A>G p.S338G | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.031); catalogued as COSV99618071; called by muse, mutect2
- C4BPA | c.144C>T p.G48= | Splice Region (SNP) | VAF 22/93 reads (24%) | catalogued as COSV100891121, COSV104424548; called by muse, mutect2, varscan2
- C9orf72 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.23); catalogued as rs774440971, COSV101186471; called by muse, mutect2, varscan2
- C9orf78 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs758042858, COSV100989950; called by muse, mutect2, varscan2
- CACNA1F | c.3001G>A p.G1001R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782473510, COSV100544284; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1G | c.5284G>A p.V1762M | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV100661046; called by muse, mutect2, varscan2
- CALML6 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV100205433; called by muse, mutect2, varscan2
- CAMSAP1 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1049080690, COSV100409513; called by muse, mutect2, varscan2
- CARD6 | c.1784T>A p.I595N | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.112); catalogued as rs1273492433, COSV54565143; called by muse, mutect2, varscan2
- CASR | c.2438G>A p.R813H (on ENST00000490131; = p.R890H on NM_000388.4) | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.681); catalogued as rs567996888, COSV56142012; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC116 | c.1484G>A p.R495Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs139995363; called by muse, varscan2
- CCDC63 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs536653873, COSV57528815; called by muse, mutect2, varscan2
- CCER1 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs777284354, COSV100726925, COSV62646542; called by muse, mutect2, varscan2
- CD163L1 | c.3499G>A p.V1167I | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.503); catalogued as rs749248792, COSV100549550; called by muse, mutect2, varscan2
- CDK5R1 | c.878G>A p.S293N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100531892; called by muse, mutect2, varscan2
- CELSR1 | c.6410C>T p.A2137V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs749849021, COSV99416477; called by muse, mutect2, varscan2
- CEP76 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as rs752539145, COSV50865921; called by muse, mutect2, varscan2
- CEP89 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201321869; called by muse, varscan2
- CERCAM | c.973A>G p.I325V | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.591); catalogued as COSV100863797, COSV104425633; called by muse, mutect2, varscan2
- CFAP47 | c.5216T>C p.F1739S | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.265); catalogued as COSV100544828; called by muse, mutect2, varscan2
- CHD1 | c.3161G>A p.R1054Q | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as rs768256433, COSV99399009; called by muse, mutect2, varscan2
- CHD3 | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV100390551; called by muse, mutect2, varscan2
- CHD8 | c.3628C>T p.R1210W (on ENST00000646647 / NM_001170629.2; = p.R931W on NM_020920.4) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757278444, COSV67873025; called by muse, mutect2, varscan2
- CHRNA3 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766076436, COSV58775382; called by muse, mutect2, varscan2
- CLCC1 | c.1348G>A p.A450T (on ENST00000356970 / NM_001377464.1; = p.A400T on NM_015127.5) | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.028); catalogued as rs755037232, COSV100206168; called by muse, mutect2, varscan2
- CLCN3 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs1249693885, COSV61626361; called by muse, mutect2, varscan2
- CLDN14 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.457); catalogued as rs371297575; called by muse, mutect2, varscan2
- CLEC16A | c.1931C>T p.T644M | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68500071; called by muse, mutect2, varscan2
- CLEC9A | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as rs142470425; called by muse, mutect2, varscan2
- CLHC1 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs755855981, COSV68463551, COSV68463940; called by muse, mutect2, varscan2
- CLSPN | c.3991C>T p.R1331* | Nonsense Mutation (SNP) | VAF 26/56 reads (46%) | catalogued as rs373647280; called by muse, mutect2, varscan2
- CNKSR1 | c.860C>T p.P287L (on ENST00000374253 / NM_001297647.2; = p.P280L on NM_006314.3) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs200509229, COSV64163702; called by muse, mutect2, varscan2
- CNN2 | c.787G>A p.G263S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as rs77830704; called by muse, mutect2, varscan2
- CNOT1 | c.4313G>A p.R1438Q | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99799113; called by muse, mutect2, varscan2
- CNOT11 | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99179216; called by muse, mutect2, varscan2
- CNTLN | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.983); catalogued as rs771708016, COSV99262484; called by muse, mutect2, varscan2
- CNTRL | c.3550C>T p.Q1184* | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as COSV99440872; called by muse, mutect2, varscan2
- COG3 | c.2392G>A p.A798T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs906134143, COSV100596344; called by muse, mutect2
- COL23A1 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs371042680; called by muse, mutect2, varscan2
- COL4A4 | c.4700C>T p.A1567V | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs779005474, COSV61635483; called by muse, mutect2, varscan2
- COL5A1 | c.2440G>A p.G814S | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1430715311, COSV65670525; called by muse, mutect2, varscan2
- COL6A1 | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs201227573, COSV100719853; called by muse, mutect2, varscan2
- COL9A3 | c.1021C>T p.R341* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100673254, COSV100673516; called by muse, mutect2, varscan2
- COPS7A | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57527065; called by muse, mutect2, varscan2
- COQ8A | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs767899984, COSV64656953; called by muse, mutect2, varscan2
- CPNE6 | c.1670C>T p.P557L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV53746538; called by muse, mutect2, varscan2
- CROCC | c.3520C>T p.R1174W | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1369378524, COSV100978029; called by muse, mutect2, varscan2
- CRX | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1313125094, COSV99704327; called by muse, mutect2, varscan2
- CSMD1 | c.2834C>T p.P945L (on ENST00000520002; = p.P944L on NM_033225.6) | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59329833; called by muse, mutect2
- CSPG4 | c.5983C>T p.R1995W | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs529993656, COSV57902610; called by muse, mutect2, varscan2
- CSPG4 | c.1471C>T p.R491* | Nonsense Mutation (SNP) | VAF 55/144 reads (38%) | catalogued as rs757011081, COSV57895646; called by muse, varscan2
- CTBP2 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as rs753056905, COSV100456049; called by muse, mutect2, varscan2
- CTC1 | c.3542G>A p.C1181Y | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as COSV100236087; called by muse, mutect2, varscan2
- CTDP1 | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143464787; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTDP1 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.197); catalogued as rs1471272224, COSV50002848, COSV50009557; called by mutect2, varscan2
- CTIF | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs373584006; called by muse, mutect2, varscan2
- CTSC | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.108); catalogued as rs565001276, COSV57059033; called by muse, mutect2, varscan2
- CUX1 | c.439C>T p.R147* (on ENST00000292535 / NM_181552.4; = p.R158* on NM_001913.5) | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as rs782297523, COSV52890867; called by muse, mutect2
- CYP2A7 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as COSV99393601; called by muse, mutect2, varscan2
- CYP2J2 | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201789916, COSV100967928; called by muse, mutect2, varscan2
- CYP2W1 | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs551358645, COSV100417080; called by muse, mutect2, varscan2
- DAB2IP | c.3491G>A p.R1164H (on ENST00000408936; = p.R1040H on NM_138709.2) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as rs771507565, COSV99404544; called by muse, mutect2, varscan2
- DAGLA | c.1270G>A p.G424S | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs1224417279, COSV99943891; called by muse, mutect2, varscan2
- DBN1 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV52788285; called by muse, mutect2, varscan2
- DBX1 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as COSV99910079; called by muse, mutect2, varscan2
- DCAF12L2 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs765247772, COSV63581337; called by muse, mutect2, varscan2
- DCHS1 | c.3092C>A p.P1031H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV100201362; called by muse, mutect2, varscan2
- DCLK3 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV101373853; called by muse, mutect2, varscan2
- DDX27 | c.2345G>A p.R782Q | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs756848518, COSV65599042; called by muse, mutect2, varscan2
- DDX39A | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs948792548, COSV99660090; called by muse, mutect2, varscan2
- DENND5A | c.3761T>G p.I1254S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV100063902; called by muse, mutect2, varscan2
- DGKG | c.2303C>T p.A768V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs558355832, COSV53961879, COSV99402248; called by muse, mutect2, varscan2
- DHX37 | c.1046C>T p.T349M | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1241271677, COSV100438910; called by muse, mutect2, varscan2
- DHX57 | c.1837G>A p.V613I | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs374119423; called by muse, mutect2, varscan2
- DIP2A | c.4585G>A p.V1529M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768385594, COSV100595032; called by muse, mutect2, varscan2
- DISP2 | c.3718G>A p.A1240T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.058); catalogued as COSV99139646; called by muse, mutect2, varscan2
- DLGAP3 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.005); catalogued as rs749205640, COSV52393377; called by muse, mutect2, varscan2
- DLGAP4 | c.1849C>T p.R617* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV59417493; called by muse, mutect2, varscan2
- DLK2 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55087509; called by muse, mutect2, varscan2
- DMTF1 | c.68A>G p.Q23R | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.444); catalogued as rs763560047, COSV100487198; called by muse, mutect2, varscan2
- DNAH10 | c.6052G>A p.V2018M (on ENST00000409039; = p.V1957M on NM_207437.3) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.176); catalogued as rs551358752, COSV101291894; called by muse, mutect2, varscan2
- DNAI2 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.104); catalogued as rs1004416796, COSV56758947, COSV56761940; called by muse, mutect2, varscan2
- DNM3 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs527384140, COSV62455336; called by muse, mutect2, varscan2
- DOCK2 | c.4511C>T p.T1504M | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs201320169, COSV56944226; called by muse, mutect2, varscan2
- DSCAM | c.299A>T p.Y100F | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101258863; called by muse, mutect2, varscan2
- DYNC1H1 | c.1660G>A p.D554N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1003040427, COSV100794273; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- E2F1 | c.1303del p.L435Wfs*58 | Frame Shift Del (DEL) | VAF 19/51 reads (37%) | catalogued as rs1409099723, COSV55776265; called by mutect2, pindel, varscan2
- EDC3 | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs774528932, COSV100165736; called by muse, mutect2, varscan2
- EEA1 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs557361655, COSV59285114; called by muse, mutect2, varscan2
- EEF2KMT | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99275354; called by muse, mutect2, varscan2
- EEPD1 | c.1323G>T p.K441N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV99631651; called by muse, mutect2, varscan2
- EFEMP2 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as rs550977800, COSV100337150; called by muse, mutect2, varscan2
- EFHC1 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs778852957, COSV64135934; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EIF3I | c.298G>A p.G100S | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs750288369, COSV59083899; called by muse, mutect2, varscan2
- EIF4A2 | c.211T>C p.Y71H | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99960948; called by muse, mutect2, varscan2
- ELAPOR2 | c.1460T>C p.L487P (on ENST00000450689 / NM_001142749.3; = p.L320P on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99788047; called by muse, mutect2, varscan2
- ELFN2 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.264); catalogued as rs760548220, COSV68746931; called by muse, varscan2
- EMC1 | c.2902G>A p.V968I | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.572); catalogued as rs775293691, COSV100916404; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EML1 | c.1732G>A p.V578I | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs376629514, COSV99214370, COSV99215314; called by muse, mutect2, varscan2
- ENTPD8 | c.1367C>T p.A456V (on ENST00000371506 / NM_001033113.2; = p.A419V on NM_198585.3) | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as rs757857009, COSV58161077; called by muse, mutect2, varscan2
- EP400 | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57775432; called by muse, mutect2, varscan2
- EPHB3 | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as rs754275959, COSV57805377; called by muse, mutect2, varscan2
- ETFDH | c.1378G>A p.G460R | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as rs989125087, CM1313473, COSV100306676; called by muse, mutect2, varscan2
- ETV5 | c.147T>A p.D49E | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100111961; called by muse, mutect2, varscan2
- EXOC3L1 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1180878232, COSV99333356; called by muse, mutect2, varscan2
- EXTL3 | c.2650G>A p.V884M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as rs141463126; called by muse, mutect2, varscan2
- EYA1 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs756885537, COSV58166205; called by muse, mutect2, varscan2
- EZH2 | c.1025G>A p.R342Q (on ENST00000460911 / NM_001203247.2; = p.R347Q on NM_004456.5) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100237251, COSV57447201, COSV57462530; called by mutect2, varscan2
- FAM120A | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.167); catalogued as COSV99464278; called by muse, mutect2, varscan2
- FAM124A | c.1549A>G p.T517A (on ENST00000322475 / NM_001242312.2; = p.T553A on NM_145019.4) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99696110; called by muse, mutect2, varscan2
- FAM160A2 | c.2336G>A p.R779H (on ENST00000449352 / NM_001098794.2; = p.R793H on NM_032127.4) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1382831224, COSV99791644; called by muse, mutect2, varscan2
- FAM200A | c.163A>G p.T55A | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1372492456, COSV101282697; called by muse, mutect2
- FAM237A | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs376047346, COSV69305109; called by muse, mutect2, varscan2
- FAM47A | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as rs769448337, COSV60495012, COSV60495976; called by muse, mutect2, varscan2
- FAM83C | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1394541952, COSV100981504; called by muse, mutect2, varscan2
- FAP | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as rs769751511, COSV51862099, COSV51867397; called by muse, mutect2, varscan2
- FAT4 | c.2203C>T p.R735W | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.685); catalogued as rs775165068, COSV67889091; called by muse, mutect2, varscan2
- FBLN7 | c.938C>T p.T313M | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374648225; called by muse, mutect2, varscan2
- FBN3 | c.3314C>T p.T1105M | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs145578557; called by muse, mutect2, varscan2
- FBXO31 | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61150847; called by muse, mutect2, varscan2
- FCGBP | c.7951G>A p.E2651K | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.61); catalogued as rs755987497, COSV55456112; called by muse, mutect2, varscan2
- FIGN | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as rs568198210, COSV60764452; called by muse, mutect2, varscan2
- FILIP1 | c.2456C>T p.T819M | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs370823048; called by muse, mutect2, varscan2
- FILIP1L | c.2190G>A p.M730I (on ENST00000354552 / NM_182909.3; = p.M490I on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs1310310530, COSV100496125; called by muse, mutect2, varscan2
- FIZ1 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV99684424; called by muse, mutect2, varscan2
- FLG | c.6715C>T p.R2239W | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs767399613, COSV64237417; called by muse, mutect2, varscan2
- FLOT1 | c.983G>A p.G328E | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100899806; called by muse, mutect2, varscan2
- FLRT1 | c.1211C>T p.T404M | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.917); catalogued as rs369112014, COSV99734514; called by muse, mutect2, varscan2
- FOXK2 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); catalogued as rs139388643, COSV58882688; called by muse, mutect2, varscan2
- FOXN3 | c.1430C>T p.T477M (on ENST00000261302; = p.T455M on NM_005197.4) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769831252, COSV54315829; called by muse, mutect2, varscan2
- FRAS1 | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as rs775289665, COSV53588682, COSV53636436; called by muse, mutect2, varscan2
- FRY | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs778573468, COSV100968683; called by muse, mutect2, varscan2
- FYB2 | c.2125G>T p.G709C | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100599135; called by muse, mutect2
- GABRP | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as rs773277344, COSV54662976; called by muse, mutect2, varscan2
- GAN | c.1745G>A p.R582H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs773845697, COSV101633954, COSV73720801; called by muse, mutect2, varscan2
- GAP43 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV100525230, COSV59343119; called by muse, mutect2, varscan2
- GAPVD1 | c.979A>T p.I327L | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.833); catalogued as COSV99782538; called by muse, mutect2, varscan2
- GATA6 | c.1727C>T p.S576L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV52527102; called by muse, mutect2, varscan2
- GDF11 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs753523328, COSV99143954; called by muse, mutect2, varscan2
- GIGYF2 | c.3467C>T p.T1156I | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV101003786; called by muse, mutect2
- GNB2 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1424516740, COSV51941863; called by muse, mutect2, varscan2
- GNPTAB | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV68450029; called by muse, mutect2, varscan2
- GOLGA2 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1204251912, COSV68597023; called by muse, mutect2, varscan2
- GOLM1 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV57415322; called by muse, mutect2, varscan2
- GPC6 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1357289814, COSV65494787, COSV65525111; called by muse, mutect2, varscan2
- GPR32 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.283); catalogued as rs149533633, COSV99567049; called by muse, mutect2, varscan2
- GPR55 | c.450G>A p.W150* | Nonsense Mutation (SNP) | VAF 20/37 reads (54%) | catalogued as COSV101235646, COSV67407870; called by muse, mutect2, varscan2
- GREB1 | c.2795C>T p.T932M | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0.197); catalogued as rs776903357, COSV52197070; called by muse, mutect2, varscan2
- GRIN2A | c.1805G>T p.G602V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100407879, COSV58022699; called by muse, mutect2, varscan2
- GTF3C1 | c.4361G>A p.R1454H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.284); catalogued as rs776900039, COSV100648884; called by muse, mutect2, varscan2
- GTF3C4 | c.1855G>A p.D619N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.022); catalogued as rs1564356001, COSV100935867; called by muse, mutect2
- GZMM | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.533); catalogued as rs780505573, COSV99198799; called by muse, mutect2, varscan2
- HAUS3 | c.1714T>A p.F572I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99704115; called by muse, varscan2
- HCFC1 | c.3796C>A p.P1266T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as COSV100128289, COSV100129553; called by muse, mutect2
- HDAC8 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV101002338; called by muse, mutect2, varscan2
- HDLBP | c.3410G>A p.R1137H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100189749; called by muse, mutect2, varscan2
- HERC2 | c.12536G>A p.R4179Q | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767443136, COSV55326059; called by muse, mutect2, varscan2
- HKDC1 | c.586C>T p.H196Y | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100664333; called by muse, mutect2, varscan2
- HLA-G | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs768731691, COSV64405068, COSV64406211; called by muse, mutect2
- HMG20B | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs1285917944, COSV99502950; called by muse, mutect2, varscan2
- HNRNPD | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100002685; called by muse, mutect2, varscan2
- HRNR | c.889G>A p.G297S | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs771199419, COSV64257627; called by muse, mutect2, varscan2
- HS3ST3B1 | c.1046T>C p.L349P | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100714429; called by muse, mutect2, varscan2
- HSPG2 | c.4649G>A p.R1550H | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs936183951, COSV65971419; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HSPG2 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); catalogued as rs560206345, COSV65929952; called by muse, mutect2, varscan2
- HSPH1 | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as COSV60710144; called by muse, mutect2, varscan2
- HTT | c.7961C>T p.T2654M | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs375426084; called by muse, mutect2, varscan2
- HYAL2 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs782372348, COSV100753806; called by muse, mutect2, varscan2
- HYDIN | c.11305C>T p.R3769* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | catalogued as rs746719490, COSV101124773; called by muse, mutect2, varscan2
- ICE1 | c.1033T>C p.S345P | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99663489; called by muse, mutect2, varscan2
- IGLL5 | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.624); catalogued as rs201375434; called by muse, mutect2, varscan2
- IKBKE | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149219314, COSV65625476; called by muse, mutect2, varscan2
- IMPA2 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs779089972, COSV99302349; called by muse, mutect2, varscan2
- INCENP | c.2189G>A p.R730Q (on ENST00000394818 / NM_001040694.2; = p.R726Q on NM_020238.3) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs753193933, COSV99610584; called by muse, mutect2, varscan2
- INHA | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs761632829, COSV99216045; called by muse, mutect2, varscan2
- INSR | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.227); catalogued as COSV57167823; called by mutect2, varscan2
- IP6K3 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.266); catalogued as rs564909198, COSV99539547; called by muse, mutect2, varscan2
- IPMK | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs535168447, COSV64244886; called by muse, mutect2, varscan2
- IRAG1 | c.2077C>T p.R693C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs893679901, COSV101351177, COSV70210967; called by muse, mutect2, varscan2
- ISM1 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768938941, COSV52603958; called by muse, mutect2, varscan2
- ITFG2 | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs775781549, COSV57389241, COSV99957953; called by muse, mutect2, varscan2
- ITGA11 | c.59C>T p.T20M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.153); catalogued as rs754238550, COSV100240770; called by muse, mutect2, varscan2
- ITGB2 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs757334504, CM120016, COSV56611479; called by muse, mutect2, varscan2
- ITGB5 | c.1263G>A p.T421= | Splice Region (SNP) | VAF 21/35 reads (60%) | catalogued as rs778010440, COSV56150396; called by muse, mutect2, varscan2
- JADE2 | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs778831748, COSV99252626; called by muse, mutect2, varscan2
- JMJD1C | c.3922C>T p.R1308C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.609); catalogued as rs766701870, COSV59514046; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- JPH3 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs781280078, COSV52475561; called by muse, mutect2, varscan2
- JRK | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs1554635923, COSV101401012; called by muse, mutect2, varscan2
- KANSL3 | c.2696G>A p.R899H (on ENST00000666923 / NM_001349262.2; = p.R873H on NM_001115016.3) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.964); catalogued as rs1209781034, COSV100830848; called by muse, mutect2, varscan2
- KAT6A | c.5600C>T p.A1867V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.758); catalogued as rs145754397; called by muse, mutect2, varscan2
- KATNB1 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs782421954, COSV101109899; called by muse, mutect2, varscan2
- KCNB1 | c.347G>A p.S116N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.777); catalogued as COSV65568072; called by muse, mutect2, varscan2
- KCNIP1 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV61081139; called by muse, mutect2, varscan2
- KCNQ2 | c.1997C>T p.P666L (on ENST00000359125 / NM_172107.4; = p.P638L on NM_004518.6) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as rs762130930, COSV60540199; called by muse, mutect2, varscan2
- KDM5A | c.3597del p.G1200Dfs*9 | Frame Shift Del (DEL) | VAF 16/34 reads (47%) | catalogued as rs771545848; called by mutect2, varscan2
- KIDINS220 | c.3934G>A p.E1312K | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.029); catalogued as COSV99874782; called by muse, mutect2, varscan2
- KIF21A | c.4402G>A p.A1468T (on ENST00000361418 / NM_001378440.1; = p.A1455T on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.979); catalogued as COSV100735228; called by muse, mutect2, varscan2
- KITLG | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs1461795798, COSV99933069; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLF3 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV54710638; called by muse, mutect2, varscan2
- KLF7 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1232482014, COSV100518906; called by muse, mutect2, varscan2
- KLHL13 | c.485A>T p.D162V | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as COSV53247976, COSV99450856; called by muse, mutect2, varscan2
- KLHL41 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as rs576773055, COSV52931986, COSV99500204; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KMT2C | c.2719C>T p.R907* | Nonsense Mutation (SNP) | VAF 20/84 reads (24%) | catalogued as COSV100065173; called by muse, varscan2
- KMT2D | c.8048G>A p.R2683H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56470322; called by muse, mutect2, varscan2
- LAMA4 | c.4644C>A p.Y1548* (on ENST00000230538 / NM_001105206.3; = p.Y1541* on NM_002290.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as COSV100037451; called by muse, mutect2, varscan2
- LCA5 | c.1676C>T p.S559L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766143193, CM1310822, COSV63972165; called by muse, mutect2, varscan2
- LCE2D | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.251); catalogued as rs550712261, COSV64229250; called by muse, mutect2, varscan2
- LCN8 | c.368G>A p.R123Q (on ENST00000612714 / NM_001345934.1; = p.R100Q on NM_178469.3) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs368173889, COSV100293258; called by muse, mutect2, varscan2
- LDLRAP1 | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs901050187, COSV65474213; called by muse, mutect2, varscan2
- LIMS1 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.632); catalogued as rs377342624; called by muse, mutect2, varscan2
- LIMS2 | c.473C>T p.A158V (on ENST00000355119 / NM_001161403.3; = p.A182V on NM_017980.4) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.084); catalogued as COSV99760373; called by muse, mutect2, varscan2
- LINGO1 | c.1714G>A p.V572I | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62438903; called by muse, mutect2, varscan2
- LINGO1 | c.1477G>A p.G493S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs529899301, COSV100796262; called by muse, mutect2, varscan2
- LMNB2 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs771415464, COSV100321883; called by muse, mutect2
- LMNTD1 | c.1032C>G p.Y344* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV99279266; called by muse, mutect2, varscan2
- LNP1 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.023); catalogued as rs894128219, COSV101051195; called by muse, mutect2, varscan2
- LRIG3 | c.2101C>T p.R701W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771630854, COSV100292373; called by muse, varscan2
- LRIG3 | c.1651C>T p.H551Y | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV100292374; called by muse, mutect2, varscan2
- LRP1 | c.6541G>A p.A2181T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs377241209; called by muse, mutect2, varscan2
- LRP10 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as rs771209105, COSV62079117; called by muse, mutect2
- LRRC1 | c.19C>A p.L7M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as COSV100905971; called by muse, mutect2, varscan2
- LRRC39 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 23/79 reads (29%) | catalogued as rs371155598; called by muse, mutect2, varscan2
- LRRC66 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV58634191, COSV58636302; called by muse, mutect2
- LVRN | c.1802G>A p.R601Q | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767111956, COSV100773287; called by muse, mutect2, varscan2
- MACF1 | c.4852C>T p.R1618W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as rs755180011, COSV99240692; called by muse, mutect2, varscan2
- MACF1 | c.12725G>A p.R4242Q (on ENST00000372915; = p.R2175Q on NM_012090.5) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | catalogued as rs202091396, COSV99240694; called by muse, varscan2
- MAD1L1 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777976890, COSV99764943; called by mutect2, varscan2
- MAGEB1 | c.989C>T p.T330M | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs145293151, COSV100974796; called by muse, mutect2, varscan2
- MANBAL | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs755003934, COSV101009407; called by muse, mutect2, varscan2
- MAP1B | c.3868G>A p.A1290T | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV99701662; called by muse, mutect2, varscan2
- MARK3 | c.2153G>A p.C718Y (on ENST00000429436 / NM_001128918.3; = p.C694Y on NM_002376.6) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99357694; called by muse, mutect2, varscan2
- MBD1 | c.101A>G p.Y34C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99495273; called by muse, mutect2, varscan2
- MCC | c.1955C>T p.T652M | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as rs751790153, COSV56731024; called by muse, mutect2, varscan2
- MCF2L | c.2198G>A p.R733H (on ENST00000375608; = p.R701H on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs774936427, COSV56175265; called by mutect2, varscan2
- MCTP1 | c.2095C>T p.R699* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as rs751396813, COSV56505812; called by muse, mutect2, varscan2
- ME3 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150824447; called by muse, mutect2, varscan2
- MED17 | c.1621G>A p.A541T | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs754273143, COSV99315638; called by muse, mutect2, varscan2
- MED25 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777343496, COSV100457005; called by muse, mutect2, varscan2
- MED25 | c.1528G>A p.V510M | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV57202615; called by muse, mutect2, varscan2
- MED27 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs146748316; called by muse, mutect2, varscan2
- MEGF8 | c.2477G>A p.R826Q (on ENST00000251268 / NM_001271938.2; = p.R759Q on NM_001410.3) | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); catalogued as rs775071124, COSV99234113; called by muse, mutect2, varscan2
- MEGF8 | c.3004C>T p.R1002W (on ENST00000251268 / NM_001271938.2; = p.R935W on NM_001410.3) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1374279391, COSV52078519, COSV99234119; called by muse, mutect2, varscan2
- MFSD11 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs763350082, COSV60620942; called by muse, mutect2, varscan2
- MGA | c.5452C>T p.R1818* (on ENST00000219905 / NM_001164273.1; = p.R1609* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 41/78 reads (53%) | catalogued as COSV54950284; called by muse, mutect2, varscan2
- MGAT5B | c.2062G>A p.A688T (on ENST00000569840 / NM_001199172.2; = p.A686T on NM_144677.3) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs367906821; called by muse, mutect2, varscan2
- MLLT1 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV53130687, COSV53133326; called by muse, mutect2, varscan2
- MMP2 | c.1942G>A p.V648M | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.829); catalogued as rs557085579, COSV50895600, COSV99528206; called by muse, mutect2, varscan2
- MOGAT2 | c.584G>T p.R195M | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.95); catalogued as COSV99549325; called by muse, mutect2, varscan2
- MOGS | c.1693C>T p.R565W | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745841543, COSV99270225; called by muse, mutect2, varscan2
- MORC3 | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV68203612; called by muse, mutect2, varscan2
- MRPL27 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as rs768545678, COSV56811752; called by muse, mutect2, varscan2
- MRPS18B | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 21/41 reads (51%) | catalogued as rs1561867937, COSV52543020; called by muse, mutect2, varscan2
- MRPS31 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as rs757451497, COSV60267041; called by muse, mutect2, varscan2
- MSI1 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as rs761676109, COSV57455830; called by muse, mutect2, varscan2
- MTCL1 | c.1748G>A p.R583Q (on ENST00000306329 / NM_001378206.1; = p.R223Q on NM_015210.4) | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs754737702, COSV100093194; called by muse, mutect2, varscan2
- MTCL1 | c.4103G>A p.R1368H (on ENST00000306329 / NM_001378206.1; = p.R1049H on NM_015210.4) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs766629891, COSV100093196; called by muse, mutect2, varscan2
- MTMR4 | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1235302486, COSV100050685; called by muse, mutect2, varscan2
- MUC16 | c.19496G>A p.G6499E | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.005); catalogued as COSV101197677; called by muse, mutect2, varscan2
- MUC20 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs528684754, COSV100290845; called by mutect2, varscan2
- MUC4 | c.13077C>T p.Y4359= (on ENST00000463781 / NM_018406.7; = p.Y123= on NM_004532.6) | Splice Region (SNP) | VAF 10/40 reads (25%) | catalogued as rs781585715, COSV100203238; called by muse, mutect2, varscan2
- MUC5B | c.9004A>G p.T3002A | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.189); catalogued as COSV101499983; called by muse, mutect2, varscan2
- MYH7 | c.3148C>T p.R1050* | Nonsense Mutation (SNP) | VAF 9/62 reads (15%) | catalogued as rs730880767, COSV100805614; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH7B | c.1363G>A p.V455M | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as rs371353626; called by muse, mutect2
- MYO1C | c.2828C>T p.T943M (on ENST00000648651 / NM_001080779.2; = p.T908M on NM_033375.5) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs367849804; called by muse, mutect2, varscan2
- MYO1D | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.96); catalogued as rs369774478; called by muse, mutect2, varscan2
- MYO5A | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.041); catalogued as rs527359862, COSV62560348; called by muse, mutect2, varscan2
- MYO7A | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as rs782255256, COSV68687032; called by muse, mutect2, varscan2
- N4BP3 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs772298001, COSV51070384; called by muse, mutect2, varscan2
- NADSYN1 | c.760G>A p.V254I | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1337954666, COSV59814153; called by muse, mutect2, varscan2
- NAGLU | c.1505A>G p.Y502C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99863925; called by muse, mutect2, varscan2
- NALCN | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199687023, COSV51938654; called by muse, varscan2
- NAV2 | c.2803C>T p.R935* (on ENST00000396087 / NM_001244963.2; = p.R912* on NM_145117.5) | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as COSV100584519; called by muse, mutect2, varscan2
- NAV3 | c.4082C>T p.P1361L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs751841384, COSV57116183; called by muse, mutect2, varscan2
- NAV3 | c.6944G>A p.R2315Q (on ENST00000397909 / NM_001024383.2; = p.R2293Q on NM_014903.6) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs552595814, COSV57078453, COSV57096626; called by muse, mutect2, varscan2
- NBEAL2 | c.5689G>A p.G1897S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs370113557; called by muse, mutect2, varscan2
- NELFB | c.910G>A p.V304M | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as rs756174445, COSV58024941; called by muse, mutect2, varscan2
- NENF | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761532512, COSV65341595; called by muse, mutect2, varscan2
- NEO1 | c.3415C>T p.R1139* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV56077343; called by muse, mutect2, varscan2
- NIBAN3 | c.1637G>T p.G546V | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.167); catalogued as COSV99961700; called by muse, mutect2
- NIN | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1348032914, COSV55381045; called by muse, mutect2, varscan2
- NIPBL | c.3220C>T p.R1074C | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99238383; called by muse, mutect2, varscan2
- NLRP4 | c.2464G>A p.E822K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.158); catalogued as rs140263319, COSV56710538; called by muse, mutect2, varscan2
- NOB1 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs768728190, COSV99263827; called by muse, mutect2, varscan2
- NRBP2 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as rs372417243; called by muse, mutect2, varscan2
- NUCB1 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375589971; called by muse, mutect2
- NYX | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV61180356; called by muse, mutect2
- OAS3 | c.2300G>A p.R767H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as rs550299718, COSV99965983; called by muse, mutect2, varscan2
- OBSL1 | c.3338G>A p.R1113H | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.871); catalogued as rs1162974945, COSV54705212; called by muse, mutect2, varscan2
- OPLAH | c.2273G>A p.R758H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200773486, COSV101470702; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR14J1 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372401214; called by muse, mutect2, varscan2
- OR2H2 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs776753816, COSV100589377; called by muse, mutect2, varscan2
- OR2M3 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs199968773, COSV71759103; called by muse, mutect2, varscan2
- OR51A4 | c.781G>A p.V261I | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs763198309, COSV66748968; called by muse, mutect2, varscan2
- OR51G2 | c.926C>T p.T309M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.198); catalogued as rs200630145, COSV58992505; called by muse, mutect2, varscan2
- OR56A1 | c.500C>A p.S167Y | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV100360374, COSV57362145, COSV57363898; called by muse, mutect2, varscan2
- OR6C4 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.02); catalogued as rs762612300, COSV67793177; called by muse, mutect2, varscan2
- OR9Q2 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV61111488; called by muse, mutect2, varscan2
- OSBPL7 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs377181361; called by muse, mutect2, varscan2
- P3H3 | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs373813652; called by muse, mutect2, varscan2
- P4HTM | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs568151159, COSV100637506; called by muse, mutect2, varscan2
- PABPN1 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs758290474, COSV99391082; called by muse, mutect2
- PAN2 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs370516391, COSV57754284; called by muse, mutect2, varscan2
- PARD3B | c.1864C>T p.R622* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as rs1370671456, COSV100591870; called by muse, mutect2, varscan2
- PATZ1 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs5753567, COSV99315036; called by muse, mutect2, varscan2
- PBX3 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.899); catalogued as rs747241535, COSV60732288; called by muse, mutect2, varscan2
- PCDHAC2 | c.1103C>T p.T368M | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1223315916, COSV53871703, COSV99144157; called by muse, mutect2, varscan2
- PCDHB8 | c.566G>A p.G189D | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.558); catalogued as rs782225002, COSV99175301; called by muse, mutect2, varscan2
- PCDHGA1 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV65295131; called by muse, mutect2, varscan2
- PCDHGA3 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); catalogued as rs757266874, COSV53976111; called by muse, mutect2, varscan2
- PCDHGC3 | c.1153G>A p.G385R | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52778409, COSV99341386; called by muse, mutect2, varscan2
- PCNT | c.4952G>A p.R1651H | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs908322773, COSV100854976; called by muse, mutect2, varscan2
- PCSK7 | c.916-1G>T p.X306_splice | Splice Site (SNP) | VAF 15/58 reads (26%) | catalogued as COSV100309109; called by muse, mutect2, varscan2
- PDCD11 | c.4934C>T p.A1645V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99588216; called by muse, mutect2, varscan2
- PDE1C | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as rs765331013, COSV100370606; called by muse, mutect2, varscan2
- PDZRN3 | c.1355T>A p.I452N | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99726932; called by muse, mutect2, varscan2
- PER1 | c.1363G>A p.V455M | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748359668, COSV100424197; called by muse, mutect2, varscan2
- PGPEP1L | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs370163731; called by muse, mutect2, varscan2
- PIK3R1 | c.1072C>T p.R358* (on ENST00000521381 / NM_181523.3; = p.R88* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as COSV57123913; called by muse, mutect2, varscan2
- PIK3R1 | c.1915C>T p.R639* (on ENST00000521381 / NM_181523.3; = p.R369* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 17/52 reads (33%) | catalogued as COSV57126125; called by muse, mutect2, varscan2
- PKD1L1 | c.7313G>T p.R2438M | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV99218129; called by muse, mutect2
- PLCB4 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1023472067, COSV53824448; called by muse, mutect2, varscan2
- PLCG2 | c.2194C>T p.R732C | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs369760877; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEC | c.1952G>A p.R651H (on ENST00000322810 / NM_201380.4; = p.R541H on NM_000445.5) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs781887816, COSV100509586; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLPPR4 | c.1622A>G p.Q541R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.131); catalogued as COSV64564582, COSV64564985; called by muse, mutect2, varscan2
- POT1 | c.869A>G p.K290R | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100713969; called by muse, mutect2, varscan2
- POU4F2 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.775); catalogued as rs759244883, COSV55586370; called by muse, mutect2, varscan2
- PPIG | c.408G>A p.G136= | Splice Region (SNP) | VAF 3/32 reads (9%) | catalogued as rs1178143980, COSV99644078; called by muse, mutect2
- PPP4R4 | c.459G>A p.W153* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100175570; called by muse, mutect2
- PRDM1 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1427730094, COSV64848332; called by muse, mutect2, varscan2
- PRICKLE3 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs144815821, COSV99602683; called by muse, mutect2
- PRMT2 | c.766A>G p.K256E | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.122); catalogued as COSV99388410; called by muse, mutect2, varscan2
- PRPF8 | c.5495G>A p.R1832H | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59264706; called by muse, mutect2, varscan2
- PRPSAP1 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1007035954, COSV100221585; called by muse, mutect2, varscan2
- PRR16 | c.722C>T p.P241L (on ENST00000407149 / NM_001300783.2; = p.P218L on NM_016644.2) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs201907499, COSV101086121, COSV101087988; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1447C>T p.R483* (on ENST00000352766; = p.R404* on NM_181334.5) | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as rs549516595, COSV61233972; called by muse, mutect2, varscan2
- PRUNE2 | c.6986C>T p.P2329L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs753525046, COSV100944768, COSV65037995; called by muse, mutect2, varscan2
- PTPN21 | c.2170G>A p.G724R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs200176662, COSV60851367; called by muse, mutect2, varscan2
- PTPRB | c.3968G>A p.R1323H | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs776345826, COSV54231940; called by muse, mutect2, varscan2
- PTPRC | c.1358C>T p.T453M | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs771120252, COSV61408990; called by muse, mutect2
- PUS7L | c.1783G>A p.V595I | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.628); catalogued as COSV100786445; called by muse, mutect2, varscan2
- PXK | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.505); catalogued as COSV100243797; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as rs1334635593, COSV54758031; called by muse, mutect2, varscan2
- RAB3IP | c.484C>T p.R162* (on ENST00000550536 / NM_175623.4; = p.R146* on NM_022456.5) | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as rs372760112; called by muse, mutect2, varscan2
- RAB7A | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99413810; called by muse, mutect2, varscan2
- RACGAP1 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as rs558989049, COSV56698740; called by muse, mutect2, varscan2
- RALB | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55603155, COSV55604583; called by muse, mutect2, varscan2
- RANBP2 | c.3379C>T p.R1127* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | catalogued as COSV99311079; called by muse, mutect2, varscan2
- RAPH1 | c.3181G>A p.V1061M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as rs745344469, COSV99863284; called by muse, mutect2, varscan2
- RASAL1 | c.412C>A p.H138N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.484); catalogued as COSV99921362; called by muse, mutect2, varscan2
- RASL11A | c.506T>C p.L169P | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99610956; called by muse, mutect2, varscan2
- RBM42 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs780567018, COSV99386835; called by muse, mutect2, varscan2
- RGMA | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.102); catalogued as rs763725871, COSV100224001; called by muse, mutect2, varscan2
- RNF165 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99491203; called by muse, mutect2, varscan2
- RNF213 | c.11307G>T p.K3769N | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV100299463; called by muse, mutect2
- RNF5 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs768101414, COSV100426074; called by muse, mutect2, varscan2
- ROBO1 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422415265, COSV71392568; called by muse, mutect2, varscan2
- RP1L1 | c.1007C>T p.T336M | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.14); catalogued as rs201195142, COSV66756568; ClinVar: likely benign; called by muse, mutect2, varscan2
- RP1L1 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); catalogued as rs370516875; called by muse, mutect2, varscan2
- RPL10 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV50010747; called by muse, mutect2, varscan2
- RPS6KA6 | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758041363, COSV53117486; called by muse, mutect2, varscan2
- RRAS | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs748655822, COSV55869063; called by muse, mutect2, varscan2
- RUNX3 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs144797417; called by muse, mutect2, varscan2
- RYR1 | c.3379C>T p.R1127C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs753701890, COSV62100153; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.13606C>T p.R4536C (on ENST00000389232; = p.R4537C on NM_001036.6) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768358263, COSV101211850; ClinVar: uncertain significance; called by muse, mutect2
- S100A2 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs575985349, COSV100905935; called by muse, mutect2, varscan2
- SBK2 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs750084377, COSV60015027; called by muse, mutect2, varscan2
- SEC24B | c.932G>A p.S311N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.272); catalogued as COSV99492750; called by muse, mutect2, varscan2
- SECISBP2L | c.3164C>T p.A1055V (on ENST00000559471 / NM_001193489.2; = p.A1010V on NM_014701.4) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs1384965698, COSV99959749; called by muse, mutect2, varscan2
- SENP2 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as rs756783643, COSV56195312; called by muse, mutect2, varscan2
- SENP6 | c.2149C>T p.R717C | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.918); catalogued as rs1450596753, COSV100894261; called by muse, mutect2, varscan2
- SEPTIN2 | c.75T>G p.N25K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100764906; called by muse, mutect2, varscan2
- SERPINA9 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs768342050; called by muse, mutect2, varscan2
- SETD7 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as COSV56800224; called by muse, mutect2, varscan2
- SEZ6 | c.1996C>T p.R666C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs749356911, COSV100252557; called by muse, mutect2, varscan2
- SFI1 | c.1856G>A p.R619H (on ENST00000400288 / NM_001007467.3; = p.R588H on NM_014775.4) | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs769739523, COSV101191874; called by muse, mutect2, varscan2
- SFXN4 | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs368065380; called by muse, mutect2, varscan2
- SHOX | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.68); catalogued as COSV61861198; called by muse, mutect2, varscan2
- SHPRH | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1440604738, COSV51609838; called by muse, mutect2, varscan2
- SIGLEC15 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); catalogued as rs775151990, COSV101248703, COSV101248769; called by muse, mutect2, varscan2
- SIPA1L1 | c.4837G>A p.V1613I | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.978); catalogued as rs747750831, COSV100665032; called by muse, mutect2, varscan2
- SLC12A7 | c.1913C>T p.A638V | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1278491757, COSV99369191; called by muse, mutect2
- SLC17A7 | c.144C>A p.D48E | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV99676656; called by muse, mutect2, varscan2
- SLC25A34 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV99606418; called by muse, mutect2, varscan2
- SLC25A35 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.036); catalogued as rs777769348, COSV99873643; called by muse, mutect2, varscan2
- SLC29A3 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.233); catalogued as rs371038814; called by muse, mutect2, varscan2
- SLC2A9 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs74651202; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC34A1 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.005); catalogued as rs193920767, COSV60998982; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC35F3 | c.640G>A p.A214T (on ENST00000366617 / NM_001300845.1; = p.A283T on NM_173508.4) | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762720695, COSV100784683; called by muse, mutect2, varscan2
- SLC38A10 | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.092); catalogued as rs551300314, COSV99917083; called by muse, mutect2, varscan2
- SLC5A11 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768485681, COSV61739771; called by muse, mutect2, varscan2
- SLCO4A1 | c.1163T>G p.L388R | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV99414405; called by muse, mutect2, varscan2
- SLFNL1 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs773255974, COSV100262732; called by muse, mutect2, varscan2
- SLITRK5 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100280151; called by muse, mutect2, varscan2
- SLX4 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as rs941244697, COSV99567504; called by muse, mutect2, varscan2
- SMARCAL1 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs529024384, COSV61919905; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCAL1 | c.1849C>T p.R617W | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs765565692, COSV61919777; called by muse, mutect2, varscan2
- SMC6 | c.2831A>G p.Y944C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100704702; called by muse, mutect2, varscan2
- SNCAIP | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.056); catalogued as rs778186133, COSV54417488; called by muse, mutect2, varscan2
- SOGA3 | c.2344G>A p.D782N | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs761251616, COSV64104873; called by muse, mutect2, varscan2
- SORD | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs780364484, COSV51043975, COSV99980333; called by muse, mutect2, varscan2
- SPINT4 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748266177, COSV54142341, COSV54142606; called by muse, varscan2
- SPNS1 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.411); catalogued as rs766318180, COSV57953801; called by muse, mutect2, varscan2
- SPON1 | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as rs782661541, COSV59957471; called by muse, mutect2, varscan2
- SPTBN2 | c.5305C>T p.R1769W | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs146455382, COSV100017985; called by muse, mutect2, varscan2
- SPTBN2 | c.3007G>A p.G1003S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); catalogued as rs770666144, COSV100017986; called by muse, mutect2, varscan2
- SRCAP | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99349006; called by muse, mutect2, varscan2
- SRCAP | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.079); catalogued as rs1220646218, COSV99349008; called by muse, mutect2, varscan2
- STAT3 | c.2288C>T p.S763L (on ENST00000264657 / NM_001369512.1; = p.S762L on NM_003150.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as rs140604473; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SUCO | c.2320G>A p.D774N | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs371070725, COSV99741811; called by muse, mutect2, varscan2
- SUPT16H | c.2960G>T p.G987V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99250300; called by muse, varscan2
- SWT1 | c.1967G>A p.R656H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as rs183754999, COSV62253939; called by mutect2, varscan2
- SYK | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs763445736, COSV65325734; called by muse, mutect2, varscan2
- SYT3 | c.1600G>A p.V534M | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as rs753605562, COSV100143792; called by muse, mutect2, varscan2
- TAF1 | c.3427C>T p.R1143C (on ENST00000373790 / NM_138923.4; = p.R1164C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV99334247; called by muse, mutect2, varscan2
- TAF5 | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100428186; called by muse, mutect2, varscan2
- TAOK2 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.429); catalogued as rs1377682145, COSV99663696; called by muse, mutect2, varscan2
- TARBP1 | c.4035dup p.A1346Cfs*26 | Frame Shift Ins (INS) | VAF 13/38 reads (34%) | catalogued as rs1177244008; called by mutect2, pindel, varscan2
- TBC1D19 | c.23T>C p.L8P | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV99335823; called by muse, mutect2, varscan2
- TBC1D8 | c.2641G>A p.A881T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs572578268, COSV65213547; called by mutect2, varscan2
- TBC1D8 | c.1198G>A p.V400M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1010440460, COSV100964232; called by muse, mutect2, varscan2
- TEPSIN | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs771993962, COSV100329481; called by muse, mutect2, varscan2
- TET3 | c.3005G>A p.R1002H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69643611; called by muse, mutect2, varscan2
- TFAM | c.441del p.E148Sfs*2 | Frame Shift Del (DEL) | VAF 11/25 reads (44%) | catalogued as rs544132101; called by mutect2, varscan2
- TG | c.1979C>T p.T660I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99598605; called by muse, mutect2, varscan2
- THSD7B | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0.045); catalogued as rs541618030, COSV99742979; called by muse, mutect2, varscan2
- TMC3 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.877); catalogued as rs771366814, COSV63924743; called by muse, mutect2, varscan2
- TMEM119 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs542172855, COSV67188469; called by muse, mutect2
- TMEM229B | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV62538373; called by muse, mutect2, varscan2
- TMEM50B | c.100T>G p.F34V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV101336623; called by muse, mutect2, varscan2
- TNIP1 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372798011; called by muse, mutect2, varscan2
- TNRC18 | c.3443C>T p.P1148L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs368075110; called by muse, mutect2, varscan2
- TNRC18 | c.2816C>T p.A939V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as rs767238958, COSV101269508; called by mutect2, varscan2
- TRAF3 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.048); catalogued as rs145456077; called by muse, mutect2, varscan2
- TRIM6 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); catalogued as rs1382721000, COSV53478952; called by muse, mutect2, varscan2
- TRIM72 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.446); catalogued as rs201191466, COSV57252191; called by muse, mutect2, varscan2
- TRPM4 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs748954661, COSV99418820; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRPV1 | c.2423C>T p.A808V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs977995978, COSV99438580, COSV99440962; called by muse, mutect2, varscan2
- TSN | c.456G>A p.S152= | Splice Region (SNP) | VAF 15/39 reads (38%) | catalogued as rs779727558, COSV101067425, COSV67605714; called by muse, mutect2, varscan2
- TSPAN5 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1319846566, COSV59876247, COSV99995204; called by muse, mutect2, varscan2
- TTC39B | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.782); catalogued as rs758648195, COSV52609569; called by muse, mutect2, varscan2
- TUBGCP5 | c.2680G>A p.V894M | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs147846294; called by muse, mutect2, varscan2
- TULP2 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV54387447; called by muse, mutect2
- TUT7 | c.3509C>T p.S1170L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1160363389, COSV52897734; called by muse, mutect2, varscan2
- UBAP2 | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.099); catalogued as rs780923321, COSV62545098; called by muse, mutect2, varscan2
- UBE2S | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); catalogued as rs1235935851, COSV99198757; called by muse, mutect2, varscan2
- UBE3B | c.1622+1G>A p.X541_splice | Splice Site (SNP) | VAF 7/44 reads (16%) | catalogued as rs934035216, COSV99783572; called by muse, mutect2, varscan2
- UQCRC1 | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as rs1318171772, COSV99178931; called by muse, mutect2, varscan2
- UQCRFS1 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV59184984; called by muse, mutect2
- USP35 | c.1678G>A p.A560T | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.061); catalogued as COSV101489033; called by muse, varscan2
- USP37 | c.2848C>T p.H950Y | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV99294063; called by muse, mutect2, varscan2
- USP40 | c.2987C>T p.T996M | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs562879098, COSV99295647; called by muse, varscan2
- USP44 | c.1517G>A p.S506N | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99311530; called by muse, mutect2, varscan2
- VANGL2 | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1264469825, COSV63604291; called by muse, mutect2, varscan2
- VWF | c.2554C>T p.Q852* | Nonsense Mutation (SNP) | VAF 21/61 reads (34%) | catalogued as rs772534075, COSV99777728; called by muse, mutect2, varscan2
- WDR1 | c.491C>T p.T164M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs541839425, COSV99306000; called by muse, mutect2, varscan2
- WDR86 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as rs1397174604, COSV57837897; called by muse, mutect2, varscan2
- WNT4 | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs371203462; called by muse, mutect2, varscan2
- WWC3 | c.1921C>T p.R641* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as COSV66507847; called by muse, mutect2, varscan2
- XPNPEP2 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs150009888, COSV100941379; called by muse, mutect2, varscan2
- XYLB | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as rs1212688550, COSV99263924; called by muse, mutect2, varscan2
- YTHDC1 | c.1573C>T p.R525C (on ENST00000344157 / NM_001031732.4; = p.R507C on NM_133370.4) | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV100704573, COSV100704906; called by muse, mutect2, varscan2
- YWHAG | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.999); catalogued as rs1057100383, COSV100297293; called by muse, mutect2, varscan2
- ZBTB12 | c.1325C>T p.T442M | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV100976935; called by muse, mutect2, varscan2
- ZBTB4 | c.1661C>T p.T554M | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs752288006, COSV60981453; called by muse, mutect2
- ZBTB45 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.109); catalogued as rs151253109; called by muse, mutect2, varscan2
- ZC3H10 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as rs1417301626, COSV57768433; called by muse, mutect2, varscan2
- ZC3H18 | c.2037del p.R680Gfs*5 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | catalogued as rs751577786; called by mutect2, varscan2
- ZFHX3 | c.2321C>T p.A774V | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs377474264; called by mutect2, varscan2
- ZFX | c.1324A>G p.R442G | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100457265; called by muse, mutect2, varscan2
- ZFYVE19 | c.994C>T p.R332* (on ENST00000355341 / NM_001077268.2; = p.R322* on NM_032850.5) | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as rs376725467; called by muse, mutect2, varscan2
- ZNF14 | c.1111T>A p.S371T | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100693951; called by muse, mutect2, varscan2
- ZNF653 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs527748933, COSV99541941; called by muse, mutect2, varscan2
- ZNF669 | c.871G>A p.G291S | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs769835529, COSV100594210; called by muse, mutect2, varscan2
- ZNF704 | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100589296; called by muse, mutect2, varscan2
- ZNF8 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as rs746081047, COSV99544082; called by muse, mutect2, varscan2
- ZNHIT2 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1417839083, COSV99659251; called by muse, mutect2, varscan2
- AP3D1 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ARID1A | c.1650del p.Y551Tfs*68 | Frame Shift Del (DEL) | VAF 22/67 reads (33%) | called by mutect2, pindel, varscan2
- C1orf174 | c.375_376del p.R125Sfs*4 | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | called by pindel, varscan2
- CASD1 | c.2347del p.C783Vfs*21 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- FCGBP | c.5170C>T p.R1724W | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by mutect2, varscan2
- KDF1 | c.169_170del p.S57Hfs*9 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | called by pindel, varscan2
- MSH6 | c.99del p.A34Pfs*47 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | called by mutect2, pindel*, varscan2
- MSH6 | c.2747_2748del p.F916* | Frame Shift Del (DEL) | VAF 6/15 reads (40%) | called by mutect2, varscan2
- SUPT20HL2 | c.2032C>T p.Q678* | Nonsense Mutation (SNP) | VAF 39/112 reads (35%) | called by muse, mutect2, varscan2
- TARDBP | c.1064dup p.N355Kfs*18 | Frame Shift Ins (INS) | VAF 31/83 reads (37%) | called by mutect2, pindel, varscan2
- TRAV18 | c.116C>T p.T39I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TTN | c.39632dup p.V13212Sfs*2 (on ENST00000591111; = p.V5788Sfs*2 on NM_003319.4) | Frame Shift Ins (INS) | VAF 6/22 reads (27%) | called by mutect2, pindel
- ZNF711 | c.1239del p.K413Nfs*15 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | called by mutect2, pindel, varscan2
- ABCB7 | c.1038T>C p.F346= (on ENST00000373394 / NM_001271696.3; = p.F347= on NM_004299.6) | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as COSV99503822; called by muse, mutect2, varscan2
- ABHD12 | c.642G>A p.T214= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs1160610200, COSV59285444; called by muse, mutect2, varscan2
- ACAD10 | c.1788C>T p.F596= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs755710906, COSV58156575; called by muse, mutect2, varscan2
- ADCY2 | c.1182C>T p.G394= | Silent (SNP) | VAF 34/86 reads (40%) | catalogued as rs773249308, COSV57880419; called by muse, mutect2, varscan2
- ADD2 | c.1650G>A p.E550= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV100034494; called by muse, mutect2, varscan2
- AGL | c.1911G>A p.A637= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as rs778511499, COSV54061044; ClinVar: likely benign; called by muse, mutect2, varscan2
- AGXT2 | c.1452G>A p.A484= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs372814383; called by muse, mutect2, varscan2
- AHDC1 | c.4173C>T p.D1391= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs1344183723, COSV99898780; called by muse, mutect2, varscan2
- ALDH4A1 | c.1629G>A p.S543= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs371144837; called by muse, mutect2, varscan2
- ALPK1 | c.3399C>T p.Y1133= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV99452898; called by muse, mutect2, varscan2
- ANKLE1 | c.1968C>T p.G656= (on ENST00000394458; = p.G602= on NM_152363.6) | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as rs376538704; called by muse, mutect2, varscan2
- AP4E1 | c.489C>T p.C163= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as rs144690366; called by muse, mutect2
- ARHGEF11 | c.1005G>A p.A335= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs1360345857, COSV100809579; called by muse, mutect2, varscan2
- ARHGEF7 | c.1740G>A p.T580= (on ENST00000375741 / NM_001113511.2; = p.T402= on NM_003899.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs772936008, COSV99520793; called by muse, mutect2, varscan2
- ATG2A | c.5049C>T p.H1683= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs763324740, COSV101033719; called by muse, mutect2, varscan2
- ATP1A2 | c.1881C>T p.G627= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs775031080, COSV63403937; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCL11B | c.2634C>T p.G878= (on ENST00000357195 / NM_001282237.2; = p.G807= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV61732882; called by muse, mutect2, varscan2
- BIN2 | c.1593G>A p.S531= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as rs779538427, COSV57206671; called by muse, mutect2, varscan2
- BTBD11 | c.1650C>T p.D550= (on ENST00000280758 / NM_001018072.2; = p.D87= on NM_001017523.2) | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs551383603, COSV55032136; called by mutect2, varscan2
- C14orf39 | c.1263G>A p.T421= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs746977921, COSV58780582; called by muse, mutect2, varscan2
- C1R | c.555C>T p.G185= (on ENST00000536053 / NM_001354346.2; = p.G171= on NM_001733.7) | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV99864363; called by muse, mutect2, varscan2
- CACNA1D | c.6174G>A p.A2058= (on ENST00000350061 / NM_001128840.3; = p.A2078= on NM_000720.4) | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs781755322, COSV99856341; called by muse, mutect2, varscan2
- CADM4 | c.1044G>A p.S348= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV99731275; called by muse, mutect2, varscan2
- CD6 | c.480G>A p.A160= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV100532730; called by muse, varscan2
- CDAN1 | c.3390G>A p.P1130= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs773377417, COSV51898014; called by muse, mutect2, varscan2
- CDH23 | c.8247C>T p.N2749= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs767660199, COSV56471622, COSV99818467; ClinVar: likely benign; called by mutect2, varscan2
- CDH8 | c.1476C>T p.N492= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs760001992, COSV54860501, COSV54863209; called by muse, mutect2, varscan2
- CEMIP | c.3756C>T p.D1252= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs141208931; called by muse, mutect2, varscan2
- CEP162 | c.516C>T p.N172= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs1484086618, COSV57616825; called by muse, mutect2, varscan2
- CFAP43 | c.2742G>A p.T914= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs146139626, COSV99530298, COSV99530815; called by muse, mutect2, varscan2
- CHI3L1 | c.84C>T p.Y28= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV99703752; called by muse, mutect2, varscan2
- CMSS1 | c.465G>A p.S155= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as rs375895581; called by muse, mutect2, varscan2
- CNOT1 | c.78A>C p.R26= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV100408347; called by muse, mutect2, varscan2
- COL5A1 | c.2079C>T p.P693= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as rs186098435, COSV65674228; ClinVar: likely benign; called by muse, mutect2, varscan2
- CRB2 | c.1746C>T p.D582= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs773635836, COSV100749508; called by muse, mutect2, varscan2
- CREBBP | c.744G>A p.P248= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs768197650, COSV52130279; called by muse, mutect2, varscan2
- CRX | c.723C>T p.S241= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs770257260, COSV99704329; called by muse, mutect2, varscan2
- CSF2 | c.434G>A p.*145= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs759609965, COSV99735572; called by muse, mutect2, varscan2
- CSMD2 | c.9681C>T p.S3227= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as rs372068474, COSV99587365; called by muse, mutect2
- CSNK1G2 | c.453G>A p.T151= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs745939601, COSV55339781; called by muse, mutect2
- CXCR3 | c.891C>T p.D297= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV101031525; called by muse, mutect2, varscan2
- DAB1 | c.6A>G p.S2= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV100139222; called by muse, mutect2, varscan2
- DAGLA | c.264G>A p.T88= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs774822524, COSV99943888; called by muse, mutect2, varscan2
- DCLK1 | c.666T>C p.D222= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV99708735; called by muse, mutect2, varscan2
- DCP2 | c.222G>A p.P74= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs144025307; called by muse, mutect2, varscan2
- DDX55 | c.1554T>C p.N518= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV99434114; called by muse, mutect2
- DICER1 | c.1857C>T p.D619= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs747735065, COSV100601690, COSV58625166; ClinVar: likely benign; called by muse, mutect2, varscan2
- DLGAP2 | c.2622G>A p.L874= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs1160736023, COSV101420990; called by muse, mutect2, varscan2
- DLK1 | c.948G>A p.L316= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as COSV100375003; called by muse, mutect2, varscan2
- DNAH10 | c.1179G>A p.T393= (on ENST00000409039; = p.T332= on NM_207437.3) | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as rs776207660, COSV101291893; called by muse, mutect2, varscan2
- DSC1 | c.921A>G p.T307= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV99937036; called by muse, mutect2, varscan2
- DST | c.14025C>T p.F4675= (on ENST00000361203 / NM_001374722.1; = p.F2263= on NM_015548.5) | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs373875682; called by muse, mutect2, varscan2
- DVL2 | c.225C>T p.N75= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs766636917, COSV50034656; called by muse, varscan2
- DYNC2I1 | c.1764A>G p.L588= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV101337594; called by muse, mutect2, varscan2
- EEF2K | c.363C>T p.T121= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as rs199516774, COSV53781897; called by muse, mutect2, varscan2
- EIF2A | c.1101G>A p.P367= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs182837216, COSV56407973; called by muse, mutect2, varscan2
- ELAC2 | c.2148C>T p.N716= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs759078534, COSV99309912; called by muse, mutect2, varscan2
- ELFN2 | c.1164G>A p.A388= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs764708659, COSV101297665, COSV68746371; called by muse, varscan2
- ENPP1 | c.1575A>T p.S525= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100719337; called by muse, mutect2, varscan2
- EPHB1 | c.1161G>A p.T387= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs367562212, COSV67665721; called by muse, mutect2, varscan2
- ESYT3 | c.2112C>T p.P704= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV101272618; called by muse, mutect2, varscan2
- EXT2 | c.1389C>T p.Y463= (on ENST00000343631; = p.Y496= on NM_000401.3) | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs1166915261, COSV100640488; called by muse, mutect2
- FAM219A | c.465C>T p.D155= (on ENST00000445726; = p.D138= on NM_147202.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs755817741, COSV99896630; called by muse, mutect2, varscan2
- FAM71D | c.969T>C p.S323= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100315088; called by muse, mutect2, varscan2
- FAM83G | c.633C>T p.N211= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs765402397, COSV58758465; called by muse, mutect2, varscan2
- FBN1 | c.4095C>T p.D1365= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as rs375402043; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- FCGBP | c.1602C>T p.R534= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as rs777358795; called by muse, mutect2, varscan2
- FCHSD1 | c.1470G>A p.T490= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs370137791; called by muse, mutect2, varscan2
- FLNA | c.5934G>A p.T1978= (on ENST00000369850 / NM_001110556.2; = p.T1970= on NM_001456.3) | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs781836633, COSV100774238, COSV100774347; called by muse, mutect2, varscan2
- FOXO3 | c.948C>T p.N316= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs1295864390, COSV59630803; called by muse, mutect2, varscan2
- FTCD | c.1380G>A p.S460= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as rs750312666, COSV99384607; called by muse, varscan2
- FZD7 | c.366T>G p.S122= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV99636742; called by muse, mutect2, varscan2
- FZD9 | c.1524G>A p.A508= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1327270227, COSV100289509; called by muse, mutect2, varscan2
- GAK | c.1917C>T p.D639= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as rs754410175, COSV100033001; called by muse, mutect2, varscan2
- GART | c.1767C>T p.A589= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs374385313; called by muse, mutect2, varscan2
- GFOD1 | c.729C>T p.G243= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs149994474; called by muse, mutect2, varscan2
- GJB2 | c.552G>A p.R184= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as COSV101241462; called by muse, mutect2, varscan2
- GLRA3 | c.252C>T p.I84= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs774375553, COSV56858961; called by muse, mutect2, varscan2
- GOT2 | c.225C>T p.Y75= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs780937861, COSV99803391; called by mutect2, varscan2
- GPR89A | c.141G>A p.T47= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs781965867, COSV100572318; called by mutect2, varscan2
- GRID2 | c.2154G>A p.S718= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs376175279; called by muse, mutect2, varscan2
- GSK3A | c.1218G>A p.L406= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV99725031; called by muse, mutect2, varscan2
- GYG2 | c.1461C>T p.D487= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs774182208, COSV100088627; called by muse, mutect2, varscan2
- HBP1 | c.1020C>T p.P340= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as rs777440206, COSV99752934; called by muse, mutect2, varscan2
- HDC | c.354C>T p.N118= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs1237992967, COSV51069195; called by muse, varscan2
- HDGF | c.459G>A p.A153= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs201820242, COSV61975412; called by muse, mutect2, varscan2
- HERC2 | c.6120C>T p.C2040= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as rs763230613, COSV99870334; called by muse, mutect2, varscan2
- HMCN1 | c.5412G>A p.R1804= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV99623100; called by muse, mutect2, varscan2
- HMCN1 | c.13686C>T p.A4562= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV99623102; called by muse, mutect2, varscan2
- HMGCL | c.150C>T p.I50= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs376705029; called by muse, mutect2, varscan2
- HNRNPM | c.2187C>T p.N729= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs377572358; called by muse, mutect2, varscan2
- IGSF21 | c.939C>T p.I313= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs371464766, COSV52125736; called by muse, mutect2, varscan2
- IKZF1 | c.1227C>T p.S409= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1171569498, COSV58785391; called by muse, mutect2, varscan2
- IL2RG | c.912C>T p.H304= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs145282692, COSV99340016; called by muse, mutect2, varscan2
- ITGAX | c.291G>A p.A97= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs371786173; called by muse, mutect2, varscan2
- JAG1 | c.915G>A p.P305= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs371165309; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNB2 | c.231C>T p.C77= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as COSV73050526; called by muse, mutect2, varscan2
- KCNH7 | c.1890C>T p.F630= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV100033700; called by muse, mutect2, varscan2
- KCNJ4 | c.615C>T p.R205= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs1467009252, COSV100340963; called by muse, mutect2, varscan2
- KCNJ8 | c.528C>T p.C176= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV99557335; called by muse, mutect2, varscan2
- KHSRP | c.552C>T p.S184= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs199705336; called by muse, mutect2
- KLHL42 | c.930C>T p.A310= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as rs766238877, COSV101179683; called by muse, mutect2, varscan2
- KRT83 | c.69C>T p.C23= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs747188137, COSV99531275; called by muse, mutect2, varscan2
- KRTAP5-11 | c.402T>C p.S134= | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as rs1454055260, COSV59370473; called by muse, mutect2, varscan2
- L1CAM | c.3642C>T p.S1214= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs782341083, COSV62830207; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- LAMB3 | c.1923C>T p.P641= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs751096261, COSV100620058; called by muse, mutect2, varscan2
- LRP5 | c.4035C>T p.S1345= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs773741784, COSV99591263; called by muse, mutect2, varscan2
- LUM | c.183A>G p.V61= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV99898847; called by muse, mutect2
- LZTS2 | c.1044C>T p.D348= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs527674014, COSV64652524; called by muse, mutect2, varscan2
- MAFF | c.216C>T p.R72= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV100633012; called by muse, mutect2, varscan2
- MAGIX | c.807G>A p.P269= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs1569525697, COSV100891830; called by muse, mutect2, varscan2
- MAP4K4 | c.3519A>G p.T1173= (on ENST00000347699 / NM_001242559.2; = p.T1099= on NM_004834.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV100153298; called by muse, mutect2, varscan2
- MAP7D3 | c.1164G>A p.A388= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs777114380, COSV100286081; called by muse, mutect2, varscan2
- MCF2L | c.3219G>A p.A1073= (on ENST00000375608; = p.A1041= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as rs771813966, COSV99995409; called by muse, mutect2, varscan2
- MED12 | c.4806G>A p.S1602= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as rs755218771, COSV100375588; called by muse, mutect2, varscan2
- MEGF8 | c.2538G>A p.S846= (on ENST00000251268 / NM_001271938.2; = p.S779= on NM_001410.3) | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs575383298, COSV99234116; called by muse, mutect2, varscan2
- MIA3 | c.3562T>C p.L1188= | Silent (SNP) | VAF 56/166 reads (34%) | catalogued as COSV100484731; called by muse, mutect2, varscan2
- MMAB | c.372C>T p.V124= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs371092213, COSV57170898; called by muse, varscan2
- MT1E | c.45C>T p.C15= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs948970861, COSV100042260; called by muse, mutect2, varscan2
- MT1H | c.48C>T p.A16= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs144085976; called by muse, mutect2, varscan2
- MUC5B | c.13797G>A p.T4599= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as rs780671358, COSV101499984, COSV101500386; called by muse, mutect2, varscan2
- MUSK | c.1755G>A p.A585= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs377355441, COSV51892456; ClinVar: likely benign; called by muse, mutect2
- MYT1 | c.2124C>T p.S708= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs1451973525, COSV100113809; called by muse, mutect2, varscan2
- NADK | c.951C>T p.I317= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs770339120, COSV100410577; called by muse, mutect2, varscan2
- NBAS | c.6324C>T p.H2108= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs771925902, COSV99866704; called by muse, mutect2, varscan2
- NCAM1 | c.894G>A p.A298= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs782263159, COSV57519212; called by muse, mutect2, varscan2
- NCKAP5L | c.2835C>T p.G945= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs766678116, COSV100258225; called by muse, mutect2
- NEURL4 | c.3342C>T p.G1114= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV59748956; called by muse, mutect2
- NFX1 | c.1701C>T p.C567= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs138868845; called by muse, mutect2, varscan2
- NIPBL | c.8118C>T p.D2706= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs763443745; called by muse, mutect2
- NLRP8 | c.699C>T p.Y233= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs377108884; called by muse, mutect2, varscan2
- NOL4L | c.489C>T p.D163= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs779636047, COSV100675543; called by muse, mutect2, varscan2
- NRP2 | c.2187G>A p.A729= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV99783323; called by muse, mutect2, varscan2
- NSUN5 | c.306C>T p.L102= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs150367445, COSV99392168; called by mutect2, varscan2
- NT5C | c.207C>T p.G69= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV99822555; called by muse, mutect2, varscan2
- NUCB1 | c.1029C>T p.T343= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs374570917; called by muse, mutect2, varscan2
- NUP210 | c.5499G>A p.T1833= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs147461037, COSV99595449; called by muse, mutect2, varscan2
- OLFM2 | c.1218G>A p.T406= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs1358486507, COSV99321421; called by muse, mutect2, varscan2
- OR6B2 | c.369C>T p.Y123= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs765428596, COSV99401075; called by muse, varscan2
- OSBPL8 | c.810T>C p.L270= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV99674343; called by muse, mutect2, varscan2
- OTUD7A | c.1455C>T p.R485= (on ENST00000307050 / NM_001382637.1; = p.R478= on NM_130901.3) | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs1341502606, COSV100191756; called by muse, mutect2, varscan2
- PACS2 | c.675C>T p.D225= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs781878450, COSV57655365; called by muse, mutect2, varscan2
- PCDH9 | c.1647C>A p.T549= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV100117765; called by muse, mutect2, varscan2
- PCDHA6 | c.2193G>A p.A731= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as rs536478075, COSV65341617, COSV65346997; called by muse, mutect2, varscan2
- PCDHGA7 | c.1779G>A p.A593= | Silent (SNP) | VAF 45/130 reads (35%) | catalogued as rs770501792, COSV99529047, COSV99548601; called by muse, mutect2, varscan2
- PGAP6 | c.1239C>T p.N413= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs746637627, COSV99170560, COSV99170611; called by muse, mutect2, varscan2
- PIK3C2B | c.3543C>T p.C1181= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs373269773; called by muse, mutect2, varscan2
- PIK3R4 | c.3975C>T p.P1325= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs550061438, COSV62035139; called by muse, mutect2
- PKHD1L1 | c.6870G>A p.L2290= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV101005165; called by muse, mutect2, varscan2
- PLXNB2 | c.3465G>A p.Q1155= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV100833814; called by muse, mutect2, varscan2
- PPP2R3B | c.660G>A p.L220= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV101065455; called by muse, mutect2, varscan2
- PPP6R1 | c.954C>T p.H318= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs760546435, COSV69799936, COSV69799957; called by muse, mutect2, varscan2
- PRLHR | c.1005C>T p.Y335= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs749817459, COSV99492602; called by muse, mutect2, varscan2
- PSMD3 | c.933C>T p.N311= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs780162633, COSV99227493; called by muse, mutect2, varscan2
- PTPN3 | c.114C>T p.G38= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs199740191; called by muse, mutect2, varscan2
- PTPRS | c.1689C>T p.G563= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs1468537510, COSV99508794; called by muse, mutect2, varscan2
- RAP1GAP2 | c.129G>A p.P43= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs373863724; called by muse, mutect2, varscan2
- RC3H2 | c.2997A>G p.S999= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV100605259; called by muse, mutect2, varscan2
- RGL1 | c.1980C>T p.N660= (on ENST00000360851 / NM_001297672.2; = p.N695= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs756203806, COSV100486124, COSV58996291; called by muse, mutect2, varscan2
- RIMBP3 | c.3372C>T p.T1124= | Silent (SNP) | VAF 24/134 reads (18%) | catalogued as rs535904531; called by muse, mutect2, varscan2
- RNF126 | c.873C>A p.S291= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV99293586; called by muse, mutect2, varscan2
- RNF19B | c.2025C>T p.D675= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs773164054, COSV99331121; called by muse, mutect2, varscan2
- RNF19B | c.1356C>T p.N452= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as rs569915572, COSV99331123; called by muse, mutect2, varscan2
- ROR2 | c.417C>T p.N139= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs1179983535, COSV100995413, COSV65216355; called by muse, mutect2, varscan2
- RPN2 | c.1242C>T p.F414= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as rs752016809, COSV52908749; called by muse, mutect2, varscan2
- RRP9 | c.603C>T p.H201= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs147286318; called by muse, mutect2, varscan2
- RTL9 | c.1113G>A p.A371= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs1474896375, COSV71825796, COSV71826158; called by muse, mutect2, varscan2
- SAC3D1 | c.579G>A p.S193= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as rs143585993; called by muse, mutect2, varscan2
- SALL3 | c.90G>A p.P30= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs762052260, COSV101609916; called by muse, mutect2, varscan2
- SCUBE2 | c.1872C>T p.A624= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs756050214, COSV100496246; called by muse, mutect2, varscan2
- SEMA4C | c.693C>T p.D231= | Silent (SNP) | VAF 42/102 reads (41%) | catalogued as rs762961578, COSV100560690; called by muse, mutect2, varscan2
- SERPINA1 | c.120T>C p.H40= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs368917367; called by muse, mutect2, varscan2
- SIN3A | c.999C>T p.H333= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs564686234, COSV100845011; called by muse, mutect2, varscan2
- SIX5 | c.2076C>T p.T692= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs146790068; called by muse, mutect2, varscan2
- SKP2 | c.1119T>C p.D373= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as rs1561043372, COSV99947830; called by muse, mutect2, varscan2
- SLC2A5 | c.1317G>A p.P439= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as rs775472970, COSV66235870; called by muse, mutect2, varscan2
- SLC35G5 | c.60C>T p.S20= | Silent (SNP) | VAF 35/85 reads (41%) | catalogued as rs374029388; called by muse, mutect2, varscan2
- SLC47A1 | c.975T>C p.G325= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV99564947; called by muse, mutect2, varscan2
- SLC4A3 | c.261G>A p.A87= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs750158608, COSV99812304; called by muse, mutect2, varscan2
- SLC7A6 | c.591C>T p.Y197= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as rs754259458, COSV99546332; called by muse, mutect2, varscan2
- SLX4IP | c.915C>T p.F305= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs538348335, COSV57945879; called by muse, mutect2
- SMARCA4 | c.1821C>T p.D607= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs150138332; ClinVar: likely benign; called by muse, mutect2, varscan2
- SMARCD1 | c.831C>T p.D277= | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as rs1050727, COSV67412204; called by muse, mutect2, varscan2
47 further variants in this file (0 protein-altering or splice-affecting, 33 silent, 14 other) are not listed here.
